Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4Q7, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4Q7-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time

DIAGNOSIS

- (A) UTERUS, CERVIX, BILATERAL OVARIES AND TUBES:
UTERINE MALIGNANT MIXED MULLERIAN TUMOR; TUMOR INVADES 8.0 MM INTO A 24.0 MM THICK MYOMETRIUM. (SEE COMMENT)
LYMPHOVASCULAR INVASION IS PRESENT.
Cervix with chronic inflammation and Nabothian cysts, no tumor present.
Bilateral ovaries and fallopian tubes, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Two lymph nodes, no tumor present (0/2).
- (C) RIGHT COMMON LYMPH NODE:
One lymph node, no tumor present (0/1).
- (D) LEFT PELVIC LYMPH NODES:
Five lymph nodes, no tumor present (0/5).
- (E) LEFT COMMON LYMPH NODES:
Two lymph nodes, no tumor present (0/2).
- (F) BELOW IMA PARA AORTIC LYMPH NODE:
One lymph node, no tumor present (0/1).
- (G) ABOVE IMA PARA AORTIC LYMPH NODES:
Nine lymph nodes, no tumor present (0/9).
- (H) OMENTUM, EXCISION:
Fibroadipose tissue, no tumor present.

COMMENT

The tumor is predominantly a high grade carcinoma (85%) composed of undifferentiated carcinoma and high grade serous carcinoma. The sarcomatous component has heterologous elements (malignant cartilage). The myoinvasive component is composed exclusively of carcinoma.

GROSS DESCRIPTION

- (A) UTERUS, CERVIX, BILATERAL OVARIES AND TUBES – A uterus and cervix (230 grams; 12.8 x 7.5 x 5.5 cm) with bilateral, unremarkable fallopian tubes (7.2 x 0.2 cm each), and bilateral unremarkable ovaries (1.7 x 0.9 x 0.7 cm each). The endometrium is replaced by a fleshy, exophytic tan tumor (8.5 x 6.0 x 4.0 cm) that grossly invades less than half of the myometrial thickness (2.7 cm). The cervix is grossly unremarkable.
INK CODE: Blue – anterior; black – posterior.
SECTION CODE: A1, anterior cervix; A2, posterior cervix; A3, right fallopian tube; A4, right ovary; A5, left fallopian tube; A6, left ovary; A7, tumor and anterior lower uterine segment; A8, posterior lower uterine segment; A9-A11, tumor and myometrium and serosa, full thickness; A12, A13, anterior tumor, representative; A14-A17, posterior tumor, right side to myometrium, full thickness; A18-A21, representative tumor.
- (B) LEFT PELVIC LYMPH NODES – Adipose tissue (5.0 x 2.5 x 0.7 cm) with two lymph nodes (2.5 cm; 3.0 cm).
SECTION CODE: B1, B2, one lymph node; B3, B4, one lymph node.
- (C) RIGHT COMMON LYMPH NODE – One lymph node (4.6 cm) submitted entirely in C.
- (D) LEFT PELVIC LYMPH NODES – Adipose tissue (5.5 x 3.5 x 0.7 cm) with five lymph nodes (0.9 to 2.5 cm).
SECTION CODE: D1, two lymph nodes; D2, two lymph nodes; D3, D4, one lymph node.
- (E) LEFT COMMON LYMPH NODES – Two lymph nodes (0.5 and 2.5 cm) entirely submitted in E1, E2.
- (F) BELOW IMA PARA AORTIC LYMPH NODE – Adipose tissue (3.0 x 20 x 0.5 cm) with one lymph node (2.0 cm) entirely submitted in

ICD-O-3
Mixed Mullerian Tumor 8950/3
Site: Path Endometrium C54.1
CQCF Uterus, NOS C55.9
Copied AWS 1/16/13

[page 2 of 2]
(G) ABOVE IMA PARA AORTIC LYMPH NODES – Adipose tissue (3.0 x 3.0 x 0.7 cm) with nine lymph nodes (0.4 to 3.0 cm).
• SECTION CODE: G1, four lymph nodes; G2, three lymph nodes; G3, two lymph nodes.
(H) OMENTUM – Unremarkable adipose tissue (11.0 x 7.5 x 0.5 cm) representatively submitted in H1-H4.

CLINICAL HISTORY

Uterine Cancer

SNOMED CODES

T-83020, M-89503

"Some tests reported here may have been developed and performance characteristics determined specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

se tests have not been

-----END OF REPORT-----

Preliminary: 10/10/12 LW

Prior Staging History		X
Reviewed/Initiated	LW	Date Reviewed: 10/15/12

Source: NCI Genomic Data Commons file 60110957-d048-47bd-a155-87ca841160a2 (TCGA-N9-A4Q7.0E5E42BD-AB48-4889-BFC8-1D6E6657CB85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).